Gene-level copy-number profile of tumor specimen TCGA-CD-8526-01A from TCGA case TCGA-CD-8526, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.5 years (26,840 days).
Specimen TCGA-CD-8526-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.54afe5b1-01f3-46c9-a6f4-79cff074f423.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8526-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a662603-0ed7-4746-b1d6-c9d768b518c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 4,319; copy number 2: 18,243; copy number 3: 14,958; copy number 4: 11,758; copy number 5: 3,149; copy number 6: 6,453; copy number 7: 503; copy number 8: 101; copy number 11: 1; copy number 12: 129; copy number 13: 44; copy number 14: 14; copy number 16: 29; copy number 17: 5; copy number 23: 20; copy number 24: 25; copy number 26: 1; copy number 27: 1; copy number 32: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8526-01A-11D-2338-01): tumor purity 0.32, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:71,779,491–72,447,151, 4 genes (within-gene range 0–3): CALN1, RNA5SP232, AC005011.1, ABCF2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,508 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–158,686,715, 693 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:159,998,651–160,579,516, 26 genes, copy number 7 (within-gene range 4–7): KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84.
- chr1:232,700,204–232,808,407, 4 genes, copy number 7: RNU6-1211P, LINC01745, LINC01744, MAP10.
- chr2:38,814–23,927,123, 347 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:173,297,629–173,368,997, 3 genes, copy number 6: RPS2P18, AC092573.1, CDCA7.
- chr2:193,170,704–199,191,120, 69 genes, copy number 5–6 (broad region; genes not listed).
- chr2:200,086,870–202,871,985, 103 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr3:162,486,541–164,171,556, 9 genes, copy number 6: TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263.
- chr3:166,569,693–180,325,059, 203 genes, copy number 8–32 (broad region; genes not listed).
- chr7:54,933,699–55,713,252, 17 genes, copy number 7 (within-gene range 3–7): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–8 (broad region; genes not listed).
- chr9:32,633,454–38,069,227, 227 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:60,914,407–76,932,066, 277 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–13,668,445, 242 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr10:16,207,821–38,783,108, 392 genes, copy number 6–11 (broad region; genes not listed).
- chr12:66,767–41,574,745, 893 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:45,215,987–118,430,699, 1,637 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:118,888,434–133,214,832, 455 genes, copy number 5 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 2–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr18:47,390–2,049,510, 46 genes, copy number 5–12 (within-gene range 4–12): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:12,328,944–24,708,542, 188 genes, copy number 5–14 (within-gene range 4–14) (broad region; genes not listed).
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–16,053,197, 291 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:15,552,157–64,313,132, 1,162 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
